Somatic mutation profile of tumor specimen TARGET-20-PARUNX-09A (aliquot TARGET-20-PARUNX-09A-01D) from TARGET case TARGET-20-PARUNX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,321 days).
Specimen TARGET-20-PARUNX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d41ef34-1463-4d6d-bc9b-5ad82394f5d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUNX-14A (Bone Marrow Normal), aliquot TARGET-20-PARUNX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1ffb1a1-3be0-454f-84e7-2373878e03c5

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs374333820, COSV58786758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 48/382 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AKAP6 | c.5161C>T p.R1721C | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs758563777, COSV55209326; called by muse, mutect2, varscan2
- CENPBD1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs191266164, COSV51921357; called by muse, mutect2, varscan2
- COL6A1 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV62612919; called by muse, mutect2, varscan2
- MAGEA10 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV54885843, COSV54886058; called by muse, mutect2, varscan2
- MUC5B | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374693051; called by muse, mutect2, varscan2
- MYO6 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs551471138, COSV64121378; called by muse, mutect2, varscan2
- POF1B | c.1452G>C p.Q484H | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53140426; called by muse, mutect2, varscan2
- OTUD6A | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SRSF10 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 56/764 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2
- COL7A1 | c.3612G>A p.A1204= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs762604188, COSV60402910; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMPD4 | c.3459C>T p.D1153= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs1427946992, COSV66215045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- IL22RA2 | c.417G>T p.S139= | Silent (SNP) | VAF 21/252 reads (8%) | called by muse, mutect2
- KIRREL2 | c.702G>A p.S234= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs771624645, COSV52880058; called by muse, mutect2, varscan2
- PRKCQ | c.1218C>T p.F406= | Silent (SNP) | VAF 124/375 reads (33%) | catalogued as rs1211148985, COSV54119112; called by muse, mutect2, varscan2
- SOX14 | c.132C>T p.A44= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs750669644, COSV60163440; called by muse, mutect2, varscan2
